TCGA case TCGA-92-7340 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - St. Louis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/86b165c2-d0e6-4a4f-84ed-aa95e3133627

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 45.0 years (16,447 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 82 days; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Number of cycles: 4; Treatment dose: 789 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 50; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Number of cycles: 4; Treatment dose: 398 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 50; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 82 days; Disease response: With Tumor.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Adjuvant Therapy.
- Karnofsky performance status: 80; ECOG performance status: 2; Timepoint: Preoperative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 15; Tobacco smoking onset year: 1985; Tobacco smoking quit year: 2000.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-92-7340-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1.1; Shortest dimension: 0.3.
  Slide TCGA-92-7340-01A-01-BS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 60; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 20.
- Samples TCGA-92-7340-01D, TCGA-92-7340-01E (2 with the same recorded description): Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample TCGA-92-7340-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-92-7340-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-92-7340-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1.1; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form: Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 82 days; disease-specific survival: no event (censored), 82 days; progression-free interval: no event (censored), 82 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-92-7340-01A-21D-2041-01): tumor purity 0.39, ploidy 2.11, whole-genome doublings 0.
